Somatic mutation profile of tumor specimen C3N-00149-02 (aliquot CPT0084560006) from CPTAC case C3N-00149, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.4 years (24,990 days).
Specimen C3N-00149-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7380225-8cf9-4e3c-a001-86a3363e58ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00149-31 (Blood Derived Normal), aliquot CPT0085310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/965d2ede-06c5-43de-af90-79e9bcd271ad

The open-access MAF lists 103 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 15, Frame Shift Del 11, Intron 10, RNA 3, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 164/332 reads (49%) | catalogued as rs5030829, CM156382, CM941369, COSV56543353, COSV56543426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AOC1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs867599399; called by muse, mutect2, varscan2
- APOB | c.12531del p.V4178Lfs*7 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV51938628; called by mutect2, pindel, varscan2
- ATP6V0A2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 115/395 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1295585374, COSV100376830; called by muse, mutect2, varscan2
- CACNA1H | c.6769C>T p.R2257W | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770202267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYLC1 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV61414494; called by muse, mutect2, varscan2
- DENND4A | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs1350242757; called by muse, mutect2, varscan2
- DMD | c.6862C>A p.Q2288K | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967525950, CM103845; called by muse, mutect2, varscan2
- INTS8 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1311719361; called by muse, mutect2, varscan2
- MMP17 | c.1059C>A p.Y353* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs1314106394; called by muse, mutect2, varscan2
- OLIG1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1457760135, COSV60737713; called by muse, varscan2
- PCMTD1 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62124592; called by muse, mutect2, varscan2
- PKD1L1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs1348702474; called by muse, mutect2, varscan2
- RBM48 | c.731del p.L244Cfs*6 | Frame Shift Del (DEL) | VAF 84/274 reads (31%) | catalogued as rs770281416; called by mutect2, pindel, varscan2
- SEMA5B | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99533137; called by muse, mutect2, varscan2
- TGFBR2 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050762, CM159806, COSV55442586, COSV55450248; called by muse, mutect2, varscan2
- TRPC7 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs536224426; called by muse, mutect2, varscan2
- TTI1 | c.293del p.S98* | Frame Shift Del (DEL) | VAF 66/302 reads (22%) | catalogued as COSV65060289, COSV65063743; called by mutect2, pindel, varscan2
- AASS | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABL1 | c.3016A>C p.I1006L | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ATP6V0A2 | c.497_521+3del | Frame Shift Del (DEL) | VAF 31/242 reads (13%) | called by mutect2, pindel
- BAP1 | c.2057-1G>C p.X686_splice | Splice Site (SNP) | VAF 117/224 reads (52%) | called by muse, mutect2, varscan2
- C3 | c.4187A>T p.Q1396L | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CALR | c.35_45del p.L12Rfs*44 | Frame Shift Del (DEL) | VAF 98/445 reads (22%) | called by mutect2, pindel, varscan2
- CCDC63 | c.1108T>G p.L370V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDC42EP4 | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH11 | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 92/455 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CPEB4 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4A | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DTNB | c.1430C>A p.T477K | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EIF2AK1 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EXPH5 | c.3443del p.D1148Vfs*5 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by pindel, varscan2
- FAM126B | c.695T>G p.L232W | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FER1L5 | c.5717A>T p.K1906M (on ENST00000623019; = p.K1870M on NM_001293083.2) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FYB1 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCG | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- GOLGA6L2 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2
- GRM1 | c.2647del p.A883Qfs*35 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | called by pindel, varscan2
- GTSE1 | c.1569C>G p.S523R | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- HIPK1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HK1 | c.2390T>C p.L797P | Missense Mutation (SNP) | VAF 124/464 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ICE1 | c.3739A>T p.N1247Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IL4R | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MAPK8IP3 | c.3641G>T p.R1214M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MED15 | c.1699A>G p.K567E (on ENST00000263205 / NM_001003891.3; = p.K527E on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTX1 | c.784del p.W262Gfs*2 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- MYDGF | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- N4BP2L2 | c.2665A>G p.I889V (on ENST00000674422; = p.I460V on NM_033111.4) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV2 | c.1418C>A p.T473N (on ENST00000396087 / NM_001244963.2; = p.T450N on NM_145117.5) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL1 | c.1869del p.F623Lfs*46 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- NDUFAF7 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NECTIN2 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPBL | c.96_120del p.L32Ffs*7 | Frame Shift Del (DEL) | VAF 26/272 reads (10%) | called by mutect2, pindel
- NUCKS1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OS9 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PIK3R3 | c.758T>A p.I253N | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PRDX1 | c.267dup p.T90Yfs*3 | Frame Shift Ins (INS) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1393A>T p.N465Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PYGM | c.31del p.R11Efs*15 | Frame Shift Del (DEL) | VAF 47/189 reads (25%) | called by mutect2, pindel, varscan2
- RSU1 | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- RXRB | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMM50 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAP30BP | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SPINK5 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 105/424 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- STAB1 | c.4184A>T p.Q1395L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRO | c.2554A>T p.T852S | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTC9 | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- VWDE | c.3542G>C p.C1181S | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF532 | c.3383A>T p.E1128V | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF644 | c.3646T>G p.L1216V | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- BFAR | c.150G>T p.G50= | Silent (SNP) | VAF 144/506 reads (28%) | called by muse, varscan2
- CYRIB | c.267A>G p.K89= | Silent (SNP) | VAF 81/217 reads (37%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1158C>T p.T386= | Silent (SNP) | VAF 18/304 reads (6%) | catalogued as rs539081624; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- DMXL1 | c.7473G>T p.R2491= | Silent (SNP) | VAF 52/152 reads (34%) | called by muse, mutect2, varscan2
- DNAH9 | c.7737G>T p.L2579= | Silent (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- DOCK2 | c.1872T>C p.R624= | Silent (SNP) | VAF 99/165 reads (60%) | called by muse, mutect2, varscan2
- LTN1 | c.2481C>T p.A827= | Silent (SNP) | VAF 108/266 reads (41%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.606G>A p.P202= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs771836602; called by muse, mutect2, varscan2
- NBEAL1 | c.1675C>A p.R559= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV101495615; called by muse, mutect2, varscan2
- NME4 | c.468G>A p.V156= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs751493049; called by muse, mutect2, varscan2
- PIWIL4 | c.1782G>A p.K594= | Silent (SNP) | VAF 77/346 reads (22%) | called by muse, mutect2, varscan2
- SDHAF2 | c.213C>T p.L71= | Silent (SNP) | VAF 87/382 reads (23%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.85C>A p.R29= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV100764909, COSV63472064; called by muse, mutect2, varscan2
- ZNHIT2 | c.183C>T p.P61= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, varscan2
- ZSCAN10 | c.1593C>G p.R531= (on ENST00000252463; = p.R586= on NM_032805.3) | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- AMN | c.1007-38C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1174452449; called by mutect2, varscan2
- CRYM | c.674-34T>C | Intron (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+830C>T | Intron (SNP) | VAF 25/82 reads (30%) | catalogued as rs1048716567; called by muse, mutect2, varscan2
- MOG | c.731-218G>A | Intron (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- NBPF7 | n.867C>G | RNA (SNP) | VAF 29/164 reads (18%) | catalogued as rs1171243133; called by muse, mutect2, varscan2
- NBPF9 | c.2476+731G>T | Intron (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9155039 del A | 5'Flank (DEL) | VAF 41/137 reads (30%) | called by mutect2, pindel, varscan2
- RAD23A | c.-73C>T | 5'UTR (SNP) | VAF 28/118 reads (24%) | catalogued as rs960563311; called by muse, mutect2, varscan2
- RPL23AP42 | n.238C>A | RNA (SNP) | VAF 36/316 reads (11%) | catalogued as rs1190429890; called by muse, mutect2, varscan2
- RRP7A | c.217-109G>A | Intron (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- RYR3 | c.10023+9C>A | Intron (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- SEMA4C | c.1673-23C>T | Intron (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SH2D6 | n.652G>A | RNA (SNP) | VAF 43/204 reads (21%) | catalogued as rs755907033, COSV61064383; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3461C>T | Intron (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- SYTL5 | c.1155+610G>A | Intron (SNP) | VAF 35/142 reads (25%) | called by muse, varscan2
- TCP11L1 | c.*2G>A | 3'UTR (SNP) | VAF 14/120 reads (12%) | catalogued as rs199505063; called by muse, varscan2
- UBR7 | c.*426T>G | 3'UTR (SNP) | VAF 167/436 reads (38%) | called by muse, mutect2, varscan2
- VLDLR | c.-380G>T | 5'UTR (SNP) | VAF 67/126 reads (53%) | called by muse, mutect2, varscan2
